Somatic mutation profile of tumor specimen BA3002D (aliquot aq-BA3002D) from BEATAML1.0 case 2172, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.8 years (23,301 days).
Specimen BA3002D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 602d8ffc-8180-42cb-97f8-7a0e3c6c882e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2042D (Solid Tissue Normal), aliquot aq-BA2042D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11ce3bf0-e91d-4bb9-8eac-10360ae19948

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 8, Intron 4, Nonsense Mutation 2, Splice Region 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 27/52 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 44/145 reads (30%) | catalogued as rs1423753702, CM971594, COSV60067818, COSV60068249, COSV60071382, COSV60073329, COSV60074859, COSV60075137; ClinVar: pathogenic; called by muse, varscan2
- ADARB2 | c.1973G>C p.R658T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.055); catalogued as COSV104430295, COSV67182732; called by muse, mutect2, varscan2
- CPS1 | c.4112G>A p.R1371Q | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs765106604, CM114387, COSV51802810, COSV51802996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSTYK | c.2012A>G p.N671S | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764174507, COSV65688612; called by muse, mutect2, varscan2
- GRM3 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1365944007, COSV64467506, COSV64477994; called by muse, mutect2, varscan2
- KPNB1 | c.1806G>C p.Q602H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV51598408; called by muse, varscan2
- MUC16 | c.8894C>A p.S2965Y | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV67476345; called by muse, mutect2, varscan2
- PCDHA5 | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs1554129382, COSV100972409, COSV65353946; called by muse, varscan2
- RYR3 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs776257846, COSV66793170; called by muse, mutect2, varscan2
- SETD2 | c.4877T>C p.F1626S | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57437059; called by muse, mutect2, varscan2
- SORCS2 | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs753277765; called by muse, varscan2
- SPTB | c.6776+8C>T | Splice Region (SNP) | VAF 124/254 reads (49%) | catalogued as rs772384819; called by muse, mutect2, varscan2
- WNK3 | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100671842; called by muse, mutect2
- WT1 | c.1214-1G>A p.X405_splice | Splice Site (SNP) | VAF 25/305 reads (8%) | catalogued as COSV60071959, COSV60081752; called by muse, mutect2
- WT1 | c.959T>A p.L320* | Nonsense Mutation (SNP) | VAF 27/218 reads (12%) | catalogued as COSV60083321; called by mutect2, varscan2
- ZSCAN32 | c.997G>T p.A333S (on ENST00000396846; = p.A354S on NM_017810.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV59237688; called by muse, mutect2
- ANKRD13D | c.*257C>A | Splice Region (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- ARHGEF17 | c.4720C>A p.P1574T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.778); called by muse, mutect2
- BTBD11 | c.2041G>C p.E681Q (on ENST00000280758 / NM_001018072.2; = p.E218Q on NM_001017523.2) | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CCDC102B | c.45C>G p.I15M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- CLYBL | c.365C>G p.T122S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EFTUD2 | c.2716A>G p.I906V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GRIP1 | c.974C>G p.T325S | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIP1R | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MAML2 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- SACS | c.8729A>G p.N2910S | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SPATA31A3 | c.693C>G p.D231E | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- STK24 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- WT1 | c.1107_1117del p.A370Qfs*2 | Frame Shift Del (DEL) | VAF 22/147 reads (15%) | called by pindel, varscan2
- CLCN5 | c.2049C>G p.L683= | Silent (SNP) | VAF 51/220 reads (23%) | catalogued as COSV56583642; called by muse, mutect2, varscan2
- EGF | c.1636C>A p.R546= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as rs756376698; called by muse, mutect2, varscan2
- ELP5 | c.84G>C p.V28= | Silent (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2
- IRX6 | c.186G>A p.P62= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV99306903; called by muse, mutect2, varscan2
- SMG7 | c.2529G>A p.Q843= | Silent (SNP) | VAF 58/115 reads (50%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.837G>C p.P279= | Silent (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- VWDE | c.177C>G p.L59= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs780638670; called by muse, mutect2, varscan2
- WNK2 | c.2067C>T p.P689= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs372392898, COSV52936882; called by muse, mutect2, varscan2
- ABI3BP | c.1576+6256G>A | Intron (SNP) | VAF 24/49 reads (49%) | catalogued as rs538665614; called by muse, mutect2, varscan2
- AMPH | c.1182+1284C>G | Intron (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- CADM1 | c.1078+11167C>T | Intron (SNP) | VAF 19/124 reads (15%) | catalogued as rs751019520; called by muse, mutect2, varscan2
- CPEB1 | c.371-1601G>C | Intron (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
